Somatic mutation profile of tumor specimen 0DU07Q from CCDI case PBCJIN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: External ear; Age at diagnosis: 1.4 years (529 days).
Specimen 0DU07Q: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e319beb-46bc-43c0-836f-ab9b9817dfbe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU07L (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f01176f4-e39f-4df3-aba9-39c44caef674

The open-access MAF lists 23 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 3, Silent 3, 3'UTR 2, 5'UTR 2, Nonsense Mutation 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 403/946 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by mutect2, varscan2
- IGSF9B | c.2366C>T p.T789M | Missense Mutation (SNP) | VAF 100/771 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.769); catalogued as rs947845439; called by muse, mutect2, varscan2
- LILRA4 | c.35-7C>T | Splice Region (SNP) | VAF 17/436 reads (4%) | catalogued as rs1433071149; called by muse, mutect2
- NFE2L1 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 88/673 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs370850258; called by muse, mutect2, varscan2
- PWWP2B | c.1769C>T p.T590M | Missense Mutation (SNP) | VAF 44/290 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762657112; called by muse, mutect2, varscan2
- RALGAPB | c.4411C>G p.R1471G | Missense Mutation (SNP) | VAF 155/1000 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV99484672; called by muse, mutect2, varscan2
- SHANK2 | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 52/451 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as rs782699631, COSV53589267, COSV99572189; called by muse, mutect2, varscan2
- DHX34 | c.2758C>G p.L920V | Missense Mutation (SNP) | VAF 21/470 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by muse, mutect2
- IGSF3 | c.655G>A p.V219M | Missense Mutation (SNP) | VAF 41/403 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ITGAD | c.3045+1G>T p.X1015_splice | Splice Site (SNP) | VAF 69/705 reads (10%) | called by muse, mutect2
- PNISR | c.1297C>T p.Q433* | Nonsense Mutation (SNP) | VAF 86/630 reads (14%) | called by muse, mutect2, varscan2
- UPB1 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 61/730 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2
- ZNF831 | c.3950G>T p.R1317I | Missense Mutation (SNP) | VAF 129/817 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- PIAS4 | c.1182C>T p.D394= | Silent (SNP) | VAF 89/550 reads (16%) | catalogued as rs748518702; called by muse, mutect2, varscan2
- TMEM132C | c.663G>A p.P221= | Silent (SNP) | VAF 38/266 reads (14%) | catalogued as rs1374914297; called by muse, mutect2, varscan2
- USP4 | c.2607C>T p.A869= | Silent (SNP) | VAF 36/682 reads (5%) | catalogued as rs749953171, COSV99648970; called by muse, mutect2
- ABHD17A | c.528-71G>A | Intron (SNP) | VAF 35/265 reads (13%) | called by muse, mutect2, varscan2
- MAGEB6 | c.-58C>A | 5'UTR (SNP) | VAF 45/156 reads (29%) | called by muse, mutect2, varscan2
- MLLT10 | c.240+18008G>A | Intron (SNP) | VAF 80/865 reads (9%) | catalogued as rs764402984; called by muse, mutect2
- PINK1 | c.960-40C>T | Intron (SNP) | VAF 32/249 reads (13%) | catalogued as rs562999056; called by muse, mutect2, varscan2
- UMOD | c.*67C>T | 3'UTR (SNP) | VAF 46/337 reads (14%) | catalogued as rs926186800, COSV56776593; called by muse, mutect2, varscan2
- WWOX | c.-97C>G | 5'UTR (SNP) | VAF 8/95 reads (8%) | called by muse, mutect2
- XK | c.*5A>G | 3'UTR (SNP) | VAF 121/180 reads (67%) | called by muse, mutect2, varscan2
